Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7902, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7902-01A (Primary Tumor).

Pathology Report for Subject [REDACTED]

Addendum Discussion:

The MIB-1 labeling index is calculated at up to 5.1% in the most proliferative regions. Although the MIB-1 labeling index is relatively high for a low grade oligodendroglioma, the lack of histological anaplastic features, including necrosis, microvascular proliferation, hypercellularity and mitotic figures, are more consistent with a low grade oligodendroglioma. Nonetheless, the elevated MIB-1 labeling index is worrisome and close follow-up for recurrence and/or anaplastic progression is warranted.

Addendum Diagnosis:

Oligoastrocytoma, WHO grade II

Microscopic Description:

Sections demonstrate a mildly hypercellular glial neoplasm composed predominantly of neoplastic cells with perinuclear halos and some perineuronal satellitosis. Occasional scattered large atypical hyperchromatic cells are noted. There is some edema, but no necrosis or microvascular proliferation is seen. No mitotic figures are identified.

Source: NCI Genomic Data Commons file f6cdafc0-c254-44e3-8584-68c46877b77c (TCGA-HT-7902.BB55771D-E5DC-4625-8C3C-0A6C1AAE487D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).